Surgical pathology report (de-identified scan), TCGA case TCGA-A4-7732, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-7732-01A (Primary Tumor).

[page 1 of 2]
*** Final Report ***

Clinical History

Right renal mass

Specimen

#1 Right kidney

Gross Examination

#1 Received fresh, placed in formalin and labeled right kidney is a 16.0 x 9.5 x 6.0 cm nephrectomy specimen. The specimen consists of a 358.7 gram, 13.0 x 8.5 x 5.5 cm kidney with attached perinephric adipose tissue and a 9.0 cm long, 0.3 cm in diameter ureter. The adrenal gland is not present. Within the upper to mid pole of the kidney is an 8.0 x 8.0 x 5.0 cm relatively circumscribed mass. The mass has a soft, friable, variegated golden-yellow to dull yellow and focally hemorrhagic cut surface. The mass is also focally calcified. The mass abuts and pushes against the renal capsule, but grossly does not appear to extend through it, and comes to within 0.2-0.3 cm of the radial soft tissue margin (inked black). The mass is at least 2.5 cm from the vascular margins. The parenchyma is otherwise maroon-tan with a distinct corticomedullary junction (cortex 0.7 cm and medulla 1.2 cm). There are no additional lesions identified. There are no lymph node candidates identified at the hilum. The perinephric adipose tissue is serially sectioned to demonstrate no gross focal mass or lesion. Following the written consent of the patient, fresh tissue is submitted to the [REDACTED] and the [REDACTED]

Ten representative sections submitted in seven: "A"-"G". Block Summary: "A", vascular and ureteral margins, tangential; "B", mass with respect to the renal capsule and radial margin, perpendicular; "C", additional section of mass with respect to adjacent kidney and renal capsule; "D"-"F", mass with respect to the pelvic adipose tissue; "G", uninvolved parenchyma. [REDACTED]

Microscopic Examination

#1 Microscopic examination performed. [REDACTED]

Comment

This case has been reviewed in consultation with one additional departmental pathologist. [REDACTED]

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 2 of 2]
Signature Line

Final Diagnosis

#1 RIGHT KIDNEY: PAPILLARY RENAL CELL CARCINOMA (TYPE 1).
TUMOR SIZE: 8.0 X 8.0 X 5.0 CM
SARCOMATOID FEATURES: ABSENT.
TUMOR NECROSIS: PRESENT.
HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE): II.
EXTENT OF TUMOR: TUMOR LIMITED TO KIDNEY.
LYMPH VASCULAR INVASION: ABSENT.
RENAL VEIN MARGIN STATUS: NEGATIVE.
RENAL SINUS STATUS: NEGATIVE.
RENAL CAPSULE STATUS: NEGATIVE.
PERINEPHRIC ADIPOSE TISSUE STATUS: NEGATIVE.
URETER MARGIN STATUS: NEGATIVE (>9 CM).
ADRENAL GLAND: NOT IDENTIFIED.
ADDITIONAL PATHOLOGIC FINDINGS: NONE IDENTIFIED.
LYMPH NODE STATUS: PERIRENAL LYMPH NODES NOT IDENTIFIED.

PATHOLOGIC STAGE (TNM CLASSIFICATION): pT2a pNX.

Ordering Provider

Ordering Physician:

Printed by:
Printed on:

Source: NCI Genomic Data Commons file 62406fb6-d97e-45a6-bf9e-bd8887d4ec56 (TCGA-A4-7732.2EE76492-08D4-4F56-8F75-EA2096957360.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).